Somatic mutation profile of tumor specimen TCGA-DZ-6135-01A (aliquot TCGA-DZ-6135-01A-11D-1961-08) from TCGA case TCGA-DZ-6135, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 45.1 years (16,468 days).
Specimen TCGA-DZ-6135-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f96e43e1-66ee-4cee-a86b-db1e06530e7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DZ-6135-10A (Blood Derived Normal), aliquot TCGA-DZ-6135-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae4dbd3c-f69f-49b2-8511-6afb235bbabc

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 18, Silent 11, Frame Shift Del 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3749T>C p.M1250T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913245, CM992181, COSV59255872; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.1042T>C p.S348P | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59320122; called by muse, mutect2, varscan2
- BHMT | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57155195; called by muse, mutect2, varscan2
- CCDC78 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV52403541; called by muse, mutect2, varscan2
- CHD4 | c.203G>C p.S68T | Missense Mutation (SNP) | VAF 114/372 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.059); catalogued as COSV58907099; called by muse, mutect2, varscan2
- FAM83G | c.1746A>T p.E582D | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV58760390; called by muse, mutect2, varscan2
- KLHL1 | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64777512; called by muse, mutect2, varscan2
- NFE2L3 | c.778_781del p.F260Lfs*35 | Frame Shift Del (DEL) | VAF 39/110 reads (35%) | catalogued as rs777217101; called by pindel, varscan2
- PGGT1B | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56974556; called by muse, mutect2, varscan2
- PKDREJ | c.4988T>A p.M1663K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.01); catalogued as COSV53551415; called by muse, mutect2, varscan2
- REV3L | c.8737T>A p.Y2913N | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62621562; called by muse, mutect2, varscan2
- SPTAN1 | c.3542G>T p.R1181M | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.121); catalogued as COSV63988825; called by muse, mutect2, varscan2
- SSR3 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54021118; called by muse, mutect2, varscan2
- SULT1C4 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 126/287 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55598465; called by muse, mutect2, varscan2
- TOPORS | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV62117692; called by muse, mutect2, varscan2
- TRIM28 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53401293; called by muse, mutect2, varscan2
- UBE3A | c.681A>T p.L227F | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51668779; called by muse, mutect2, varscan2
- VPS11 | c.730C>A p.Q244K (on ENST00000620429; = p.Q788K on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100333791; called by muse, mutect2, varscan2
- ZNF700 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54314375; called by muse, mutect2, varscan2
- LRP2 | c.994del p.C332Vfs*74 | Frame Shift Del (DEL) | VAF 31/131 reads (24%) | called by mutect2, pindel, varscan2
- SPRED2 | c.341del p.G114Efs*2 | Frame Shift Del (DEL) | VAF 56/177 reads (32%) | called by mutect2, pindel, varscan2
- TNC | c.4892_4930del p.A1631_D1643del | In Frame Del (DEL) | VAF 36/110 reads (33%) | called by mutect2, pindel
- ACTG2 | c.75T>C p.D25= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV61829174; called by muse, mutect2, varscan2
- CDK5R1 | c.463C>T p.L155= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV55580139; called by muse, mutect2, varscan2
- GP1BA | c.1839A>G p.V613= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as COSV56700241; called by muse, mutect2, varscan2
- HELQ | c.2817T>C p.F939= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV55026523; called by muse, mutect2, varscan2
- IL4I1 | c.846G>A p.L282= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV55580010; called by muse, varscan2
- LCE3D | c.252C>T p.C84= | Silent (SNP) | VAF 76/227 reads (33%) | catalogued as rs374860616, COSV100909893, COSV64231030; called by muse, mutect2, varscan2
- LNX2 | c.552C>T p.G184= | Silent (SNP) | VAF 104/310 reads (34%) | catalogued as rs778168392, COSV60337279; called by muse, mutect2, varscan2
- MCOLN3 | c.906C>G p.L302= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV62015215; called by muse, mutect2, varscan2
- SNX29 | c.2241C>T p.N747= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV60066234; called by muse, mutect2, varscan2
- WDR55 | c.945T>C p.H315= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1369802970, COSV56908445; called by muse, mutect2, varscan2
- ZNF615 | c.2037G>T p.P679= | Silent (SNP) | VAF 77/187 reads (41%) | catalogued as COSV65034440; called by muse, mutect2, varscan2
